Somatic mutation profile of tumor specimen C3L-00812-01 (aliquot CPT0025350009) from CPTAC case C3L-00812, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 74.8 years (27,323 days).
Specimen C3L-00812-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc2ab8e2-63b5-48c6-b541-ff1e4ea3704a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00812-31 (Blood Derived Normal), aliquot CPT0029480002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9c3d268-5a21-450a-87fa-7194d0f3700d

The open-access MAF lists 75 somatic variants for this specimen: 57 protein-altering or splice-affecting, 13 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 13, Nonsense Mutation 4, Frame Shift Del 4, 5'UTR 3, Splice Site 2, In Frame Ins 1, RNA 1, Splice Region 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.345C>A p.H115Q | Missense Mutation (SNP) | VAF 62/250 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs864622646, CM023998, CM951285, COSV56544954, COSV56545969; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AL592490.1 | c.2008C>T p.R670* | Nonsense Mutation (SNP) | VAF 7/134 reads (5%) | catalogued as rs1313291049, COSV69426707; called by muse, mutect2
- ARFGEF2 | c.2696C>T p.T899M | Missense Mutation (SNP) | VAF 101/507 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs745621774, COSV64213557; called by muse, mutect2, varscan2
- CSN1S1 | c.335T>A p.L112H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as rs988129829; called by muse, mutect2, varscan2
- DPYD | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 61/285 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs748958293, COSV64589643; called by muse, mutect2, varscan2
- LAMA5 | c.3970G>A p.V1324M | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs141276418; called by muse, mutect2, varscan2
- MYO16 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs201650171, COSV51782521; called by muse, mutect2, varscan2
- PCDH11Y | c.76G>A p.V26I (on ENST00000400457 / NM_032973.2; = p.V15I on NM_032971.3) | Missense Mutation (SNP) | VAF 17/210 reads (8%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as COSV53092562; called by muse, mutect2
- PCDHB7 | c.1161C>A p.D387E | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.182); catalogued as rs781909345, COSV50755569; called by muse, mutect2, varscan2
- RCE1 | c.753A>C p.T251= | Splice Region (SNP) | VAF 10/146 reads (7%) | catalogued as COSV58992452; called by muse, mutect2
- SIGLEC9 | c.460C>G p.L154V | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV51589205; called by muse, mutect2
- UBE3B | c.2507A>G p.Y836C | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs763834013, COSV61073234; called by muse, mutect2, varscan2
- UNC5A | c.283G>C p.G95R | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs140306147, COSV99994774; called by muse, mutect2, varscan2
- ZNF716 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as rs782303620; called by muse, mutect2
- ABCA13 | c.13460G>C p.R4487T | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABCB5 | c.3746A>C p.K1249T (on ENST00000404938 / NM_001163941.2; = p.K804T on NM_178559.6) | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ACSM2A | c.136T>C p.F46L | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ANK3 | c.12798C>A p.Y4266* (on ENST00000280772 / NM_001320874.2; = p.Y890* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 8/165 reads (5%) | called by muse, mutect2
- ARHGEF10L | c.2771T>C p.L924P | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEND3 | c.1682G>C p.R561P | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- CFH | c.211T>C p.W71R | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CUBN | c.2570A>G p.N857S | Missense Mutation (SNP) | VAF 48/244 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.406); called by muse, varscan2
- DOK7 | c.1465T>A p.F489I | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EEF1AKMT3 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 47/283 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- GABRR3 | c.1199C>A p.S400Y | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- H2BC10 | c.260G>C p.R87P | Missense Mutation (SNP) | VAF 65/257 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- HK2 | c.2252G>T p.G751V | Missense Mutation (SNP) | VAF 68/310 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSD17B13 | c.360T>G p.N120K | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA5 | c.827A>G p.K276R | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- INPP5D | c.1129G>A p.D377N (on ENST00000445964 / NM_001017915.3; = p.D376N on NM_005541.5) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- JMJD1C | c.4233G>T p.W1411C | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- KIAA1958 | c.1616A>T p.E539V | Missense Mutation (SNP) | VAF 14/357 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.216); called by muse, mutect2
- LIMA1 | c.706del p.I236* | Frame Shift Del (DEL) | VAF 20/109 reads (18%) | called by mutect2, pindel, varscan2
- LRIG2 | c.532A>T p.R178* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | called by muse, mutect2, varscan2
- LRRC46 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MALRD1 | c.2282C>G p.T761R | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by mutect2, varscan2
- MARF1 | c.2844_2851del p.L948Ffs*17 | Frame Shift Del (DEL) | VAF 44/249 reads (18%) | called by mutect2, pindel, varscan2
- MAST1 | c.3129del p.S1043Rfs*5 | Frame Shift Del (DEL) | VAF 31/118 reads (26%) | called by mutect2, pindel, varscan2
- MPO | c.856G>C p.V286L | Missense Mutation (SNP) | VAF 49/276 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.8294C>A p.S2765Y | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- PPP2R3A | c.1524G>C p.E508D | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PRDM1 | c.326del p.K109Rfs*8 | Frame Shift Del (DEL) | VAF 33/139 reads (24%) | called by mutect2, pindel, varscan2
- PRSS12 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); called by muse, varscan2
- PTCD3 | c.716+1G>A p.X239_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- PTPN22 | c.414_415insAAAAAA p.K137_K138dup | In Frame Ins (INS) | VAF 9/156 reads (6%) | called by mutect2, varscan2*
- PXDNL | c.3017G>A p.G1006D | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASEF | c.253C>G p.P85A | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- RHOC | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 38/165 reads (23%) | called by muse, mutect2, varscan2
- RLF | c.2681G>T p.S894I | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- RP1L1 | c.2378G>A p.G793E | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2
- SCN3A | c.5045A>G p.K1682R | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2
- SENP6 | c.1029C>A p.D343E | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.182); called by mutect2, varscan2
- SLIT1 | c.484T>A p.L162I | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SUN2 | c.544_555del p.W182_G185del | In Frame Del (DEL) | VAF 22/133 reads (17%) | called by mutect2, pindel, varscan2
- TBC1D2 | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VCL | c.1023-1G>T p.X341_splice | Splice Site (SNP) | VAF 57/335 reads (17%) | called by muse, mutect2, varscan2
- ZBED5 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- AFF3 | c.759G>A p.S253= | Silent (SNP) | VAF 22/191 reads (12%) | catalogued as rs371774868; called by muse, mutect2, varscan2
- APOBEC1 | c.225T>C p.D75= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV57549539; called by muse, mutect2, varscan2
- ASPHD2 | c.1026G>T p.V342= | Silent (SNP) | VAF 12/202 reads (6%) | called by muse, mutect2
- EPHB4 | c.1134T>C p.T378= | Silent (SNP) | VAF 37/176 reads (21%) | called by muse, mutect2, varscan2
- FAF1 | c.231T>G p.T77= | Silent (SNP) | VAF 60/255 reads (24%) | called by muse, mutect2, varscan2
- MS4A6A | c.486T>A p.V162= | Silent (SNP) | VAF 47/202 reads (23%) | called by muse, mutect2, varscan2
- RO60 | c.693T>G p.A231= | Silent (SNP) | VAF 32/148 reads (22%) | called by muse, mutect2, varscan2
- RSF1 | c.3984G>A p.R1328= | Silent (SNP) | VAF 30/120 reads (25%) | catalogued as COSV57836438; called by muse, mutect2, varscan2
- SENP6 | c.1239T>A p.I413= | Silent (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- SNAPC1 | c.30C>T p.D10= | Silent (SNP) | VAF 66/308 reads (21%) | catalogued as rs758545214; called by muse, mutect2, varscan2
- SON | c.5724A>G p.R1908= | Silent (SNP) | VAF 29/131 reads (22%) | called by muse, mutect2, varscan2
- TRHDE | c.909T>C p.N303= | Silent (SNP) | VAF 74/306 reads (24%) | called by muse, mutect2, varscan2
- ZBED6 | c.912A>G p.S304= | Silent (SNP) | VAF 19/108 reads (18%) | called by muse, mutect2, varscan2
- AC091163.2 | n.525C>A | RNA (SNP) | VAF 26/125 reads (21%) | called by muse, mutect2, varscan2
- C16orf87 | c.-2G>A | 5'UTR (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- SIGLEC7 | c.1125-15G>T | Intron (SNP) | VAF 40/207 reads (19%) | called by muse, mutect2, varscan2
- SLC34A1 | c.-17C>T | 5'UTR (SNP) | VAF 69/375 reads (18%) | called by muse, mutect2, varscan2
- TRMT5 | c.-74A>G | 5'UTR (SNP) | VAF 26/87 reads (30%) | catalogued as rs755881753; called by muse, mutect2, varscan2
